Somatic mutation profile of tumor specimen TCGA-SX-A7SU-01A (aliquot TCGA-SX-A7SU-01A-11D-A35Z-10) from TCGA case TCGA-SX-A7SU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 47.5 years (17,349 days).
Specimen TCGA-SX-A7SU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c546a7e6-4176-4367-a3ac-cb33d37301e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A7SU-10A (Blood Derived Normal), aliquot TCGA-SX-A7SU-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc52b325-1823-4fd6-a43a-3f50fb6e150a

The open-access MAF lists 46 somatic variants for this specimen: 39 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 6, Frame Shift Del 2, Splice Site 2, In Frame Ins 2, Nonstop Mutation 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1C3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs35575889, CM109906; called by muse, mutect2, varscan2
- ANPEP | c.2083T>C p.W695R | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100263338; called by muse, mutect2, varscan2
- BCL9L | c.3445T>C p.S1149P | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99419755; called by muse, mutect2, varscan2
- BMP5 | c.781A>C p.I261L | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100896184; called by muse, mutect2, varscan2
- C6orf58 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV100315001; called by muse, mutect2, varscan2
- CCSER1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1163480378, COSV100394467; called by muse, mutect2, varscan2
- CCSER1 | c.1544A>C p.D515A | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100394472, COSV61448997; called by muse, mutect2, varscan2
- CITED2 | c.704T>C p.M235T | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs1171612212, COSV100863123, COSV62726660; called by muse, mutect2, varscan2
- CTNNA1 | c.2179A>G p.T727A | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100243102; called by muse, mutect2, varscan2
- DMAP1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV100261782; called by muse, mutect2, varscan2
- F12 | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99499850; called by muse, mutect2, varscan2
- FRYL | c.4585G>C p.E1529Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV99977599; called by muse, mutect2, varscan2
- HNRNPH3 | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99769807; called by muse, mutect2, varscan2
- HNRNPLL | c.512T>A p.L171H | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99696629; called by muse, mutect2, varscan2
- INPP5D | c.659T>A p.L220H (on ENST00000445964 / NM_001017915.3; = p.L219H on NM_005541.5) | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100856871; called by muse, mutect2, varscan2
- KATNAL1 | c.726+1G>T p.X242_splice | Splice Site (SNP) | VAF 26/78 reads (33%) | catalogued as COSV101017083; called by muse, mutect2, varscan2
- KDM3B | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100070015; called by muse, mutect2, varscan2
- KRTAP9-3 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT deleterious (0.01); catalogued as COSV100893214, COSV100893278; called by muse, mutect2, varscan2
- MTMR3 | c.2444A>G p.D815G | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.104); catalogued as rs892045825, COSV100071151; called by muse, mutect2, varscan2
- NCCRP1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100355859; called by muse, mutect2, varscan2
- NFAT5 | c.911C>G p.S304* | Nonsense Mutation (SNP) | VAF 66/188 reads (35%) | catalogued as COSV100591083, COSV63027833; called by muse, mutect2, varscan2
- OTUD7B | c.2281A>G p.R761G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100967660; called by muse, mutect2, varscan2
- PANK1 | c.1199A>G p.K400R (on ENST00000307534 / NM_148977.2; = p.K175R on NM_138316.4) | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as rs371501466; called by muse, mutect2, varscan2
- PHAX | c.336G>C p.K112N | Missense Mutation (SNP) | VAF 114/260 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as COSV99881610; called by muse, mutect2, varscan2
- POLD1 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101486903; called by muse, mutect2, varscan2
- PTH2R | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV99782126; called by muse, mutect2, varscan2
- SLC17A8 | c.776T>A p.I259N | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100035712; called by muse, mutect2, varscan2
- SPATA16 | c.185G>T p.R62I | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100650844, COSV100651435; called by muse, mutect2, varscan2
- SYNRG | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 102/188 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.311); catalogued as rs1443974295; called by muse, mutect2, varscan2
- TCERG1 | c.3202C>G p.R1068G | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV99695101; called by muse, mutect2, varscan2
- TMEM109 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99136394; called by muse, mutect2, varscan2
- TTC26 | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100571105; called by muse, mutect2, varscan2
- TTLL4 | c.3598T>A p.*1200Kext*28 | Nonstop Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as COSV99293584; called by muse, mutect2, varscan2
- UBAP2 | c.1445A>C p.Q482P | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.854); catalogued as COSV100671722; called by muse, mutect2, varscan2
- KATNAL2 | c.1247_1249dup p.K416dup (on ENST00000356157 / NM_001353899.1; = p.K344dup on NM_031303.3 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
- KCNB1 | c.567+1del p.X189_splice | Splice Site (DEL) | VAF 42/112 reads (38%) | called by mutect2, pindel, varscan2
- PACRG | c.378del p.F126Lfs*28 | Frame Shift Del (DEL) | VAF 65/177 reads (37%) | called by mutect2, pindel, varscan2
- PEPD | c.770_775dup p.G257_H258dup | In Frame Ins (INS) | VAF 18/42 reads (43%) | called by mutect2, varscan2
- PRAG1 | c.914del p.P305Rfs*65 | Frame Shift Del (DEL) | VAF 57/179 reads (32%) | called by mutect2, pindel, varscan2
- ANPEP | c.132C>T p.S44= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as rs754187657, COSV100263340; called by muse, mutect2, varscan2
- CERT1 | c.1956A>G p.E652= (on ENST00000405807 / NM_001130105.1; = p.E524= on NM_005713.3) | Silent (SNP) | VAF 139/321 reads (43%) | catalogued as COSV99783526; called by muse, mutect2, varscan2
- NOTCH4 | c.5961C>T p.P1987= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as COSV100900839; called by muse, mutect2, varscan2
- OR8H3 | c.91C>T p.L31= | Silent (SNP) | VAF 61/118 reads (52%) | catalogued as COSV100539100, COSV57908586; called by muse, mutect2, varscan2
- PPP1R2 | c.372G>A p.E124= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV100113405; called by muse, mutect2, varscan2
- SYCP2L | c.1719C>T p.P573= | Silent (SNP) | VAF 145/371 reads (39%) | catalogued as rs748554842, COSV99305567; called by muse, mutect2, varscan2
- EXOC3 | chr5:442695 C>T | 5'Flank (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
